Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1IC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1IC-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-0-3

Melanoma, NOS 8720/3

Site: C49.9 Subcutaneous, NOS

W 3/12/11

Clinical History and Impression:

Melanoma, recurrent - previous report attached
year-old white male with two primary melanomas of left upper lateral arm 2.5 mm (T3 N0 M0 Stage II)
treated with resection [redacted] had local recurrence [redacted]

Specimen(s) Received:

- 1: MELANOMA LEFT UPPER ARM
- 2: LEFT UPPER ARM MUSCLE METASTASIS

FINAL DIAGNOSIS

1) SKIN, LEFT UPPER ARM, EXCISION:

- METASTATIC MALIGNANT MELANOMA

2) SOFT TISSUE, LEFT UPPER ARM "MUSCLE METASTASIS", EXCISION:

- METASTATIC MALIGNANT MELANOMA

Pathologist:

M.D.

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscope material and has based the diagnosis on that evaluation.

Gross Description: (redacted), M.D.)

1) Received fresh, labeled with the patient's name and "melanoma left upper arm" is an oriented 16 x 9.5 cm skin ellipse excised to a maximum depth of 1.5 cm. The epidermal surface displays multiple nodular hyperpigmented lesions ranging in size from 0.4 cm in greatest dimension to 4.8 cm in greatest dimension. There are approximately twenty of these nodules diffusely located over the surface of the specimen. One of the nodules comes to within 0.5 cm of the nearest surgical resection margin which is the 4 o'clock surgical resection margin. Gross photographs are taken. The specimen is inked as follows: 12-3-6 o'clock margin=black and the 6-9-12 o'clock=blue. The specimen is received with a previous wedge which was removed from one of the nodules and this surface is inked orange. Upon sectioning of the nodules the nodule nearest 12 o'clock as per diagram appears to be directly abutting the deep surgical resection margin within 1 mm. The specimen is represented in nine cassettes as per the diagram with the tips in cassettes #8-9 and normal skin in cassette #7.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

2) Received fresh, labeled with the patient's name, unit number and "left upper arm muscle metastasis" is a 1 x 1.1 x 0.5 cm fragment of tan-brown soft tissue which is inked black and entirely submitted in one cassette.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1) MELANOMA LEFT UPPER ARM	9	[Undes]	(9)	(No Description)
Part 2) LEFT UPPER ARM MUSCLE METASTASIS	1	[Undes]	(1)	(No Description)

Total: 10

END OF REPORT

Source: NCI Genomic Data Commons file de5b9556-a667-4044-a006-e3e097714018 (TCGA-DA-A1IC.74F640BD-4FC1-469B-9089-B7E3C04EA671.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).